Gene-level copy-number profile of tumor specimen ALCH-B0B9-TTP1-A from ALCHEMIST case ALCH-B0B9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 68.7 years (25,101 days).
Specimen ALCH-B0B9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b19ce002-99ed-4255-b91d-2dcef59993c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0B9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,218 have no estimate.
https://portal.gdc.cancer.gov/files/a02dce8a-2ae9-4f6f-a5f9-d9c7a1181698

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 9,484; copy number 2: 40,826; copy number 3: 5,464; copy number 4: 2,272; copy number 5: 344; copy number 6: 1; copy number 8: 8.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:223,947,605–223,950,416, 1 gene: CICP5.
- chr1:223,976,146–223,976,249, 1 gene: RNU6-1319P.
- chr4:74,552,584–74,589,481, 1 gene: AC239584.1.
- chr8:7,200,756–7,200,857, 1 gene: AF228730.1.
- chr17:22,298,691–22,332,410, 2 genes: FAM27E5, AC087575.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 326 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:248,623,557–248,645,278, 2 genes, copy number 5: OR2T11, OR2T35.
- chr1:248,681,322–248,682,328, 1 gene, copy number 5: OR14I1.
- chr1:248,906,196–248,937,043, 3 genes, copy number 5: PGBD2, RNU6-1205P, RPL23AP25.
- chr5:58,198–2,755,397, 80 genes, copy number 5 (broad region; genes not listed).
- chr7:1,232,872–1,237,326, 1 gene, copy number 6: UNCX.
- chr8:37,843,268–39,417,378, 50 genes, copy number 5 (within-gene range 3–5): BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5.
- chr8:39,522,976–40,520,158, 18 genes, copy number 5: AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1.
- chr10:21,513,475–21,526,368, 1 gene, copy number 8: SKIDA1.
- chr12:12,310–3,366,122, 86 genes, copy number 5 (broad region; genes not listed).
- chr20:33,031,648–35,092,807, 70 genes, copy number 5 (broad region; genes not listed).
- chr20:37,344,685–37,406,050, 1 gene, copy number 5: SRC.
- chr20:44,885,702–44,966,402, 4 genes, copy number 8: YWHAB, PABPC1L, TOMM34, STK4-AS1.
- chr20:56,688,401–56,731,460, 3 genes, copy number 8: RN7SL170P, PTMAP6, AL133232.1.
- chr20:58,069,054–58,367,507, 6 genes, copy number 5: AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A.

Autosomal genes at a single copy (total copy number 1): 8,743. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
